Somatic mutation profile of tumor specimen 0DJGDY from CCDI case PBBWAC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 13.1 years (4,783 days).
Specimen 0DJGDY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8297b97e-2fe4-4253-a927-9367d737a621.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJG6W (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/875e3442-17bd-4a4d-ba0a-73f7774c2946

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 182/1574 reads (12%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FGFR1 | c.1638C>G p.N546K (on ENST00000447712 / NM_023110.3; = p.N544K on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 103/811 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58329537, COSV58330551; called by muse, mutect2, varscan2
- STAB2 | c.3170C>T p.P1057L | Missense Mutation (SNP) | VAF 125/1474 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs754728670, COSV66339119; called by muse, mutect2
- TBATA | c.349G>A p.G117S | Missense Mutation (SNP) | VAF 78/1444 reads (5%) | SIFT tolerated (0.68); PolyPhen benign (0.078); catalogued as rs150669876, COSV99075757; called by muse, mutect2
- NF1 | c.7513dup p.A2505Gfs*31 (on ENST00000358273 / NM_001042492.3; = p.A2484Gfs*31 on NM_000267.3) | Frame Shift Ins (INS) | VAF 182/1309 reads (14%) | called by mutect2, pindel, varscan2
- CAPG | c.603G>A p.E201= | Silent (SNP) | VAF 43/1006 reads (4%) | catalogued as rs982365100; called by muse, mutect2
- BRAT1 | c.1321+17C>T | Intron (SNP) | VAF 76/598 reads (13%) | catalogued as rs756253392; called by muse, mutect2, varscan2
